Somatic mutation profile of tumor specimen TARGET-10-PAUCDC-09A (aliquot TARGET-10-PAUCDC-09A-01D) from TARGET case TARGET-10-PAUCDC, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.8 years (6,151 days).
Specimen TARGET-10-PAUCDC-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c9abbf44-fab4-4dd1-aa57-40ba93d38391.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAUCDC-10A (Blood Derived Normal), aliquot TARGET-10-PAUCDC-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d05945aa-2603-4416-a746-cd195d289f20

The open-access MAF lists 17 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Intron 4, Silent 2, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYCN | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 45/99 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519919, COSV55257406, COSV55259752; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AMBP | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs146979367; called by muse, mutect2, varscan2
- ERI3 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as rs766047284, COSV64833733; called by muse, mutect2, varscan2
- HCN1 | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57517608; called by muse, mutect2, varscan2
- KRT38 | c.248G>T p.C83F | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.174); catalogued as COSV55847690; called by muse, mutect2, varscan2
- PAH | c.176A>T p.D59V | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.111); catalogued as rs199475672, COSV61020465; ClinVar: uncertain significance; called by muse, varscan2
- SPNS2 | c.1118C>T p.T373M | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1040752212, COSV61231826; called by muse, mutect2, varscan2
- USP7 | c.974G>C p.R325P | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV61217515; called by muse, mutect2, varscan2
- HIVEP2 | c.1263_1264insTCGGTCC p.E422Sfs*14 | Frame Shift Ins (INS) | VAF 24/64 reads (38%) | called by mutect2, pindel*, varscan2
- ST7 | c.1445C>A p.S482Y | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRAMP1 | c.1731C>T p.C577= | Silent (SNP) | VAF 31/73 reads (42%) | called by muse, mutect2, varscan2
- SLC6A2 | c.633C>T p.A211= | Silent (SNP) | VAF 47/92 reads (51%) | called by muse, mutect2, varscan2
- CUTA | c.43-84C>G | Intron (SNP) | VAF 8/17 reads (47%) | called by muse, mutect2, varscan2
- E4F1 | c.1594-26G>A | Intron (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2, varscan2
- EHF | c.-4+1172G>A | Intron (SNP) | VAF 35/69 reads (51%) | called by muse, mutect2, varscan2
- SOX10 | c.*1110C>T | 3'UTR (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- TAFA5 | c.112+56937G>A | Intron (SNP) | VAF 42/93 reads (45%) | catalogued as rs999362295; called by muse, mutect2, varscan2
